Somatic mutation profile of tumor specimen C3L-00001-02 (aliquot CPT0001580165) from CPTAC case C3L-00001, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 61.5 years (22,455 days).
Specimen C3L-00001-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 59c962fd-c193-4418-8d00-d165d6054431.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00001-32 (Blood Derived Normal), aliquot CPT0000150163; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bb59f841-bf82-47d1-ad2d-173a648f2b68

The open-access MAF lists 76 somatic variants for this specimen: 53 protein-altering or splice-affecting, 16 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 16, Intron 5, Nonsense Mutation 3, Splice Region 2, In Frame Del 1, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC013489.1 | c.857C>T p.P286L | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as rs1321259346, COSV51552803; called by muse, mutect2, varscan2
- ADCY2 | c.1439G>A p.R480H | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs1410091098, COSV57859838; called by muse, mutect2, varscan2
- ADSL | c.1178G>A p.G393E | Missense Mutation (SNP) | VAF 58/518 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1232314116; called by muse, mutect2, varscan2
- ELP6 | c.712C>T p.H238Y | Missense Mutation (SNP) | VAF 41/208 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV56131551, COSV99948183; called by muse, mutect2, varscan2
- EMILIN1 | c.1064C>T p.S355F | Missense Mutation (SNP) | VAF 15/144 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.183); catalogued as rs1357851049; called by muse, mutect2, varscan2
- EYA3 | c.896A>G p.D299G | Missense Mutation (SNP) | VAF 39/173 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.648); catalogued as rs141894644; called by muse, mutect2, varscan2
- FBXO42 | c.1738C>G p.P580A | Missense Mutation (SNP) | VAF 48/180 reads (27%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.039); catalogued as COSV65046408; called by muse, mutect2, varscan2
- FKBP8 | c.1093C>T p.R365W (on ENST00000222308 / NM_001308373.2; = p.R366W on NM_012181.5) | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.092); catalogued as rs750335116; called by muse, mutect2
- KDM3A | c.1747G>T p.V583L | Missense Mutation (SNP) | VAF 17/181 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV57220069; called by muse, mutect2
- NCOA7 | c.187T>C p.Y63H | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as rs767709968; called by muse, mutect2, varscan2
- OXR1 | c.2208G>C p.W736C (on ENST00000442977 / NM_001198532.1; = p.W708C on NM_018002.3) | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770417778; called by muse, mutect2, varscan2
- PLCXD3 | c.199A>G p.T67A | Missense Mutation (SNP) | VAF 26/278 reads (9%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.973); catalogued as rs149818734; called by muse, mutect2
- PRKDC | c.5410A>G p.M1804V | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs1195801860; called by muse, mutect2, varscan2
- SCUBE1 | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 16/181 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.589); catalogued as COSV51811948; called by muse, mutect2
- STK10 | c.1688G>A p.R563H | Missense Mutation (SNP) | VAF 48/438 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs550965424, COSV51573533; called by muse, mutect2, varscan2
- TAC1 | c.232G>C p.E78Q | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.179); catalogued as COSV59987282; called by muse, mutect2, varscan2
- TNFRSF8 | c.929C>T p.T310M | Missense Mutation (SNP) | VAF 27/227 reads (12%) | SIFT tolerated (0.96); PolyPhen benign (0.001); catalogued as rs146527504; called by muse, mutect2, varscan2
- TRIL | c.649C>T p.P217S | Missense Mutation (SNP) | VAF 33/301 reads (11%) | SIFT tolerated (0.93); PolyPhen benign (0.007); catalogued as rs369693682; called by muse, mutect2, varscan2
- USH2A | c.15307G>A p.D5103N | Missense Mutation (SNP) | VAF 35/421 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.46); catalogued as rs112958319; called by muse, mutect2
- ZNF513 | c.620G>A p.R207H | Missense Mutation (SNP) | VAF 25/209 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.919); catalogued as rs752255945; called by muse, mutect2, varscan2
- ABCB1 | c.47T>G p.F16C | Missense Mutation (SNP) | VAF 88/233 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- AC244197.3 | c.766C>A p.P256T | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- AKAP4 | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 24/226 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); called by muse, mutect2
- ALAS2 | c.770C>G p.S257C | Missense Mutation (SNP) | VAF 15/339 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- AVL9 | c.1702G>A p.G568S | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CACNB1 | c.949C>T p.Q317* | Nonsense Mutation (SNP) | VAF 15/117 reads (13%) | called by muse, mutect2, varscan2
- CCDC106 | c.677C>G p.A226G | Missense Mutation (SNP) | VAF 65/427 reads (15%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CD248 | c.1969C>G p.L657V | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CSMD1 | c.6485G>T p.G2162V (on ENST00000520002; = p.G2161V on NM_033225.6) | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DIXDC1 | c.1754C>G p.S585* (on ENST00000440460 / NM_001037954.4; = p.S374* on NM_033425.4) | Nonsense Mutation (SNP) | VAF 14/176 reads (8%) | called by muse, mutect2
- DPP6 | c.1082T>A p.L361* (on ENST00000377770 / NM_001364500.2; = p.L299* on NM_001936.5) | Nonsense Mutation (SNP) | VAF 17/115 reads (15%) | called by muse, mutect2, varscan2
- EXOC3L1 | c.1054G>A p.G352R | Missense Mutation (SNP) | VAF 71/154 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- F2RL2 | c.194C>G p.T65S | Missense Mutation (SNP) | VAF 48/469 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FBXO10 | c.143T>A p.L48Q | Missense Mutation (SNP) | VAF 14/147 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FCGR3A | c.271A>C p.T91P | Missense Mutation (SNP) | VAF 79/1395 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- GLRA4 | c.13G>T p.V5F | Missense Mutation (SNP) | VAF 18/226 reads (8%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.058); called by muse, mutect2
- MAP2 | c.1333G>A p.E445K | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.689); called by muse, varscan2
- MED13 | c.2184A>G p.V728= | Splice Region (SNP) | VAF 5/58 reads (9%) | called by muse, mutect2
- NFIA | c.515T>C p.V172A | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by mutect2, varscan2
- NUS1 | c.605G>A p.R202K | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR6P1 | c.571G>C p.D191H | Missense Mutation (SNP) | VAF 38/364 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.949); called by muse, mutect2
- OSMR | c.1615A>C p.T539P | Missense Mutation (SNP) | VAF 22/228 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- RAN | c.40G>C p.V14L | Missense Mutation (SNP) | VAF 30/187 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RRAGC | c.880G>T p.D294Y | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, varscan2
- RUBCNL | c.1229G>T p.R410I | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- SLC16A10 | c.1004T>C p.I335T | Missense Mutation (SNP) | VAF 27/185 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- SMARCA4 | c.4393A>G p.I1465V | Missense Mutation (SNP) | VAF 38/209 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TDRD5 | c.1125T>C p.P375= | Splice Region (SNP) | VAF 19/76 reads (25%) | called by muse, mutect2, varscan2
- TRIM51 | c.94C>A p.H32N | Missense Mutation (SNP) | VAF 45/398 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TTN | c.12993_12998del p.E4331_F4333delinsD (on ENST00000591111; = p.E4285_F4287delinsD on NM_003319.4) | In Frame Del (DEL) | VAF 20/70 reads (29%) | called by mutect2, pindel
- XIRP2 | c.367A>G p.R123G (on ENST00000628543; = p.R298G on NM_152381.6) | Missense Mutation (SNP) | VAF 43/256 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZFP92 | c.951G>C p.E317D | Missense Mutation (SNP) | VAF 58/246 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- ZNF320 | c.170C>A p.T57K | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDH12 | c.1584A>G p.L528= | Silent (SNP) | VAF 19/218 reads (9%) | called by muse, mutect2
- COL6A5 | c.6618T>C p.N2206= (on ENST00000312481; = p.N2202= on NM_153264.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 32/118 reads (27%) | called by muse, mutect2, varscan2
- CTNS | c.159C>T p.T53= | Silent (SNP) | VAF 103/357 reads (29%) | called by muse, mutect2, varscan2
- IFT122 | c.1164A>G p.K388= (on ENST00000348417 / NM_052989.3; = p.K329= on NM_018262.4) | Silent (SNP) | VAF 26/229 reads (11%) | called by muse, varscan2
- IGKV3-7 | c.117C>G p.V39= | Silent (SNP) | VAF 53/471 reads (11%) | called by muse, mutect2, varscan2
- IQCA1 | c.1452G>A p.K484= | Silent (SNP) | VAF 20/187 reads (11%) | called by muse, mutect2, varscan2
- MFSD6 | c.1311C>T p.D437= | Silent (SNP) | VAF 20/199 reads (10%) | catalogued as rs974822904; called by muse, mutect2, varscan2
- NT5E | c.543C>A p.T181= | Silent (SNP) | VAF 10/186 reads (5%) | called by muse, mutect2
- PRSS41 | c.234G>A p.A78= | Silent (SNP) | VAF 23/226 reads (10%) | called by muse, mutect2
- RUSC1 | c.363C>G p.V121= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as rs1185333275; called by muse, mutect2, varscan2
- SAGE1 | c.1731C>T p.T577= | Silent (SNP) | VAF 4/64 reads (6%) | catalogued as rs781908009, COSV100187936; called by muse, mutect2
- SLC28A3 | c.132C>T p.S44= | Silent (SNP) | VAF 12/106 reads (11%) | called by muse, mutect2, varscan2
- SPRED1 | c.984G>A p.E328= | Silent (SNP) | VAF 53/331 reads (16%) | called by muse, mutect2, varscan2
- SPTA1 | c.4035C>T p.F1345= | Silent (SNP) | VAF 19/302 reads (6%) | called by muse, mutect2
- TAFA4 | c.243A>G p.G81= | Silent (SNP) | VAF 46/395 reads (12%) | called by muse, mutect2, varscan2
- ZNF423 | c.2598G>C p.L866= (on ENST00000563137 / NM_001379286.1; = p.L858= on NM_015069.4) | Silent (SNP) | VAF 26/178 reads (15%) | called by muse, mutect2, varscan2
- ABCG1 | c.287-11699G>A | Intron (SNP) | VAF 11/92 reads (12%) | called by muse, varscan2
- AL049777.1 | n.510+4726G>T | Intron (SNP) | VAF 20/233 reads (9%) | called by muse, mutect2
- GSDMD | c.-5+385dup | Intron (INS) | VAF 28/248 reads (11%) | called by mutect2, pindel, varscan2
- SFRP4 | c.-14G>T | 5'UTR (SNP) | VAF 25/144 reads (17%) | called by muse, mutect2, varscan2
- SHANK1 | c.2390-227C>A | Intron (SNP) | VAF 6/38 reads (16%) | catalogued as COSV53256209, COSV99521882; called by muse, mutect2, varscan2
- SPTBN1 | c.148+2851C>A | Intron (SNP) | VAF 15/142 reads (11%) | called by muse, mutect2
- TVP23A | c.*71A>G | 3'UTR (SNP) | VAF 22/122 reads (18%) | called by muse, mutect2, varscan2
